Somatic mutation profile of tumor specimen TCGA-XY-A8S2-01A (aliquot TCGA-XY-A8S2-01A-11D-A435-10) from TCGA case TCGA-XY-A8S2, project TCGA-TGCT (Testicular Germ Cell Tumors). Sex at birth: male; Vital status: Alive; Primary diagnosis: Embryonal carcinoma, NOS; Tissue or organ of origin: Testis, NOS; AJCC pathologic stage: Stage I; Age at diagnosis: 67.8 years (24,759 days).
Specimen TCGA-XY-A8S2-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 29733c8f-cb93-4165-96df-e02c536fd3fe.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-XY-A8S2-10A (Blood Derived Normal), aliquot TCGA-XY-A8S2-10A-01D-A438-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/2e13b75b-7478-4b19-a665-9cd19d0e41b0

The open-access MAF lists 64 somatic variants for this specimen: 50 protein-altering or splice-affecting, 8 silent, 6 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 40, Silent 8, Nonsense Mutation 3, Splice Site 3, In Frame Del 2, 3'UTR 2, 5'UTR 1, Frame Shift Del 1, 3'Flank 1, Intron 1, Splice Region 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AFF4 | c.1843_1845del p.K615del | In Frame Del (DEL) | VAF 35/97 reads (36%) | catalogued as rs768885773; called by pindel, varscan2
- AL031777.2 | c.367_368del p.H124Pfs*7 | Frame Shift Del (DEL) | VAF 62/272 reads (23%) | catalogued as rs749358448; called by pindel, varscan2
- ATP1A1 | c.1990G>A p.V664I | Missense Mutation (SNP) | VAF 6/40 reads (15%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.99); catalogued as rs200285355, COSV99814026; called by muse, mutect2, varscan2
- CDCA2 | c.1533+1G>A p.X511_splice | Splice Site (SNP) | VAF 8/67 reads (12%) | catalogued as rs775809553; called by muse, mutect2, varscan2
- DMD | c.6710C>G p.P2237R | Missense Mutation (SNP) | VAF 13/74 reads (18%) | SIFT tolerated (0.07); PolyPhen benign (0.001); catalogued as COSV58901995; called by muse, mutect2, varscan2
- GDF3 | c.262G>T p.D88Y | Missense Mutation (SNP) | VAF 33/219 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61712984; called by muse, mutect2, varscan2
- H1-5 | c.602C>T p.A201V | Missense Mutation (SNP) | VAF 30/141 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.007); catalogued as COSV100137781, COSV58901255; called by muse, mutect2, varscan2
- NISCH | c.245G>C p.R82T | Missense Mutation (SNP) | VAF 35/141 reads (25%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.973); catalogued as COSV51768360; called by muse, mutect2, varscan2
- NMT1 | c.507A>T p.L169= | Splice Region (SNP) | VAF 15/96 reads (16%) | catalogued as COSV51958544; called by muse, mutect2, varscan2
- NOTCH3 | c.4655A>G p.Q1552R | Missense Mutation (SNP) | VAF 9/25 reads (36%) | SIFT tolerated (0.11); PolyPhen benign (0.039); catalogued as COSV54641191; called by muse, mutect2, varscan2
- RYR3 | c.2164G>C p.G722R | Missense Mutation (SNP) | VAF 15/88 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101212005; called by muse, mutect2, varscan2
- SMC3 | c.1930C>T p.R644C | Missense Mutation (SNP) | VAF 43/100 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as rs868792707, COSV62419302; called by muse, mutect2, varscan2
- SP140 | c.2095G>T p.G699* | Nonsense Mutation (SNP) | VAF 47/190 reads (25%) | catalogued as COSV59450198, COSV59453069; called by muse, mutect2, varscan2
- ABCF2 | c.1441G>C p.E481Q | Missense Mutation (SNP) | VAF 23/174 reads (13%) | SIFT tolerated (0.15); PolyPhen benign (0.201); called by muse, mutect2, varscan2
- ACOXL | c.468C>G p.H156Q | Missense Mutation (SNP) | VAF 23/114 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- ARHGAP35 | c.389A>T p.K130I | Missense Mutation (SNP) | VAF 25/74 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- B3GNT8 | c.340G>A p.D114N | Missense Mutation (SNP) | VAF 22/47 reads (47%) | SIFT tolerated (0.49); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- CAPN7 | c.1037T>C p.I346T | Missense Mutation (SNP) | VAF 15/59 reads (25%) | SIFT tolerated (0.05); PolyPhen benign (0.141); called by muse, mutect2, varscan2
- CUL4A | c.1209C>G p.N403K (on ENST00000375440 / NM_001008895.4; = p.N303K on NM_003589.3) | Missense Mutation (SNP) | VAF 18/61 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.383); called by muse, mutect2, varscan2
- CYP24A1 | c.442C>A p.L148M | Missense Mutation (SNP) | VAF 4/42 reads (10%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.522); called by muse, mutect2
- DCLRE1C | c.603_605del p.V202del (on ENST00000378278 / NM_001350965.2; = p.V87del on NM_022487.4) | In Frame Del (DEL) | VAF 33/144 reads (23%) | called by pindel, varscan2
- DENND2B | c.2011A>C p.I671L | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT tolerated (0.59); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- DENND4C | c.3559C>T p.L1187F (on ENST00000434457 / NM_001330640.2; = p.L1138F on NM_017925.7) | Missense Mutation (SNP) | VAF 27/85 reads (32%) | SIFT tolerated (0.7); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- EID1 | c.100G>C p.G34R | Missense Mutation (SNP) | VAF 12/44 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.907); called by muse, mutect2, varscan2
- FANCM | c.5441A>T p.E1814V | Missense Mutation (SNP) | VAF 25/125 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.879); called by muse, mutect2, varscan2
- FAT3 | c.3288G>T p.E1096D | Missense Mutation (SNP) | VAF 4/50 reads (8%) | SIFT tolerated (0.51); PolyPhen benign (0.071); called by muse, mutect2
- FRYL | c.1199G>A p.R400H | Missense Mutation (SNP) | VAF 72/194 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.674); called by muse, mutect2, varscan2
- HOXC4 | c.575C>A p.S192* | Nonsense Mutation (SNP) | VAF 35/137 reads (26%) | called by muse, mutect2, varscan2
- INTS4 | c.2131T>C p.Y711H | Missense Mutation (SNP) | VAF 40/125 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); called by muse, mutect2, varscan2
- KCNC3 | c.1609G>T p.V537F | Missense Mutation (SNP) | VAF 12/39 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- KDM3B | c.4453C>T p.L1485F | Missense Mutation (SNP) | VAF 16/56 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- KNTC1 | c.1312C>G p.L438V | Missense Mutation (SNP) | VAF 20/85 reads (24%) | SIFT tolerated (0.16); PolyPhen benign (0.265); called by muse, mutect2, varscan2
- LONP1 | c.1764_1773+2del p.X588_splice | Splice Site (DEL) | VAF 13/37 reads (35%) | called by mutect2, pindel, varscan2
- MARCHF10 | c.772C>A p.P258T | Missense Mutation (SNP) | VAF 43/161 reads (27%) | SIFT tolerated (0.65); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- MED19 | c.466A>C p.T156P | Missense Mutation (SNP) | VAF 11/32 reads (34%) | SIFT tolerated (1); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- MKS1 | c.262-1G>C p.X88_splice | Splice Site (SNP) | VAF 11/40 reads (28%) | called by muse, mutect2, varscan2
- NEB | c.9034G>C p.G3012R | Missense Mutation (SNP) | VAF 17/87 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); called by muse, mutect2, varscan2
- NIPBL | c.6148A>T p.I2050F | Missense Mutation (SNP) | VAF 53/131 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); called by muse, mutect2, varscan2
- NRAP | c.4976T>C p.L1659S (on ENST00000359988 / NM_001322945.2; = p.L1624S on NM_006175.4) | Missense Mutation (SNP) | VAF 11/29 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PPP1R18 | c.1606A>T p.K536* | Nonsense Mutation (SNP) | VAF 24/121 reads (20%) | called by muse, mutect2, varscan2
- SASH3 | c.425G>A p.S142N | Missense Mutation (SNP) | VAF 91/212 reads (43%) | SIFT tolerated (0.11); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- SEMA6A | c.194A>T p.N65I | Missense Mutation (SNP) | VAF 22/141 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.603); called by muse, mutect2, varscan2
- SLC4A10 | c.1211C>T p.A404V (on ENST00000446997 / NM_001354461.2; = p.A374V on NM_022058.4 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 27/101 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- TACC2 | c.2786A>T p.E929V | Missense Mutation (SNP) | VAF 16/51 reads (31%) | SIFT tolerated (0.1); PolyPhen benign (0.049); called by muse, mutect2, varscan2
- USP6 | c.1069C>T p.P357S | Missense Mutation (SNP) | VAF 5/34 reads (15%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.857); called by muse, mutect2
- VPS13B | c.4393T>G p.L1465V | Missense Mutation (SNP) | VAF 4/72 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); called by muse, mutect2
- ZFHX3 | c.1480C>G p.L494V | Missense Mutation (SNP) | VAF 28/73 reads (38%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- ZMYND8 | c.1416C>G p.S472R (on ENST00000311275 / NM_001363741.2; = p.S492R on NM_012408.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 10/36 reads (28%) | SIFT tolerated, low confidence (0.06); PolyPhen possibly damaging (0.694); called by muse, mutect2, varscan2
- ZNF280B | c.871G>C p.G291R | Missense Mutation (SNP) | VAF 21/61 reads (34%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ZNF862 | c.437A>C p.Q146P | Missense Mutation (SNP) | VAF 14/104 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.502); called by muse, mutect2, varscan2
- AHNAK2 | c.6108C>A p.L2036= | Silent (SNP) | VAF 34/67 reads (51%) | called by muse, mutect2, varscan2
- EEF2K | c.672C>T p.P224= | Silent (SNP) | VAF 21/56 reads (38%) | catalogued as COSV99533786; called by muse, mutect2, varscan2
- ELAC2 | c.180G>A p.L60= | Silent (SNP) | VAF 10/50 reads (20%) | catalogued as rs370459638; called by muse, mutect2, varscan2
- MELK | c.1149A>C p.T383= | Silent (SNP) | VAF 31/101 reads (31%) | called by muse, mutect2, varscan2
- PLA2G4F | c.267C>T p.C89= | Silent (SNP) | VAF 10/68 reads (15%) | called by muse, mutect2, varscan2
- SERPINA9 | c.732G>A p.E244= | Silent (SNP) | VAF 13/66 reads (20%) | catalogued as COSV54078604; called by muse, mutect2, varscan2
- ZBTB37 | c.513G>A p.K171= | Silent (SNP) | VAF 31/81 reads (38%) | called by muse, mutect2, varscan2
- ZXDA | c.801C>T p.Y267= | Silent (SNP) | VAF 22/65 reads (34%) | catalogued as rs1213859915; called by muse, mutect2, varscan2
- DOK3 | c.-163_-161del | 5'UTR (DEL) | VAF 12/35 reads (34%) | called by mutect2, pindel, varscan2
- PANK2 | c.*13del | 3'UTR (DEL) | VAF 22/63 reads (35%) | called by mutect2, pindel, varscan2
- POM121 | chr7:72948713 C>T | 3'Flank (SNP) | VAF 22/103 reads (21%) | called by muse, mutect2, varscan2
- TPM1 | c.*10T>C | 3'UTR (SNP) | VAF 15/81 reads (19%) | called by muse, mutect2, varscan2
- VPS36 | c.991-10T>A | Intron (SNP) | VAF 49/117 reads (42%) | called by muse, mutect2, varscan2
- ZNF849P | n.618T>G | RNA (SNP) | VAF 60/165 reads (36%) | called by muse, mutect2, varscan2
